Gene-level copy-number profile of tumor specimen TCGA-CR-6482-01A from TCGA case TCGA-CR-6482, project TCGA-HNSC (Head and Neck Squamous Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Squamous cell carcinoma, NOS; Tissue or organ of origin: Tonsil, NOS; Tumor grade: G3; Age at diagnosis: 62.3 years (22,741 days).
Specimen TCGA-CR-6482-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-HNSC.6fe6fe99-796d-4db4-b7bf-d9e9153f5789.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-CR-6482-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 808 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/5b8f6c29-8e6c-4107-b4dd-070c32ab1e9c

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 92; copy number 2: 4,591; copy number 3: 97; copy number 4: 44,379; copy number 5: 55; copy number 6: 10,183; copy number 7: 18; copy number 14: 35; copy number 15: 122; copy number 16: 38; copy number 17: 155; copy number 21: 48; copy number 77: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-CR-6482-01): tumor purity 0.38, ploidy 2.17, whole-genome doublings 0 (call status: legacy_maf_call).

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 366 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr2:156,305,108–156,342,348, 2 genes, copy number 77: AC074099.1, NR4A2.
- chr8:125,348,196–145,066,685, 364 genes, copy number 14–21 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 92. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
